Somatic mutation profile of tumor specimen TCGA-06-6701-01A (aliquot TCGA-06-6701-01A-11D-1845-08) from TCGA case TCGA-06-6701, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.4 years (22,051 days).
Specimen TCGA-06-6701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f07e8fb-6e38-442e-9334-1723d1010cc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6701-10A (Blood Derived Normal), aliquot TCGA-06-6701-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc78176-3091-4ff9-84df-437a0197b342

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 21, Silent 10, Splice Region 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.842A>C p.D281A | Missense Mutation (SNP) | VAF 33/39 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 33/39 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOBEC3G | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as rs757807279, COSV68470017; called by muse, mutect2, varscan2
- ARHGEF28 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV55248149; called by muse, mutect2, varscan2
- CDH24 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489493621, COSV52973626; called by muse, mutect2, varscan2
- ELAPOR1 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64040001; called by muse, mutect2, varscan2
- ELOVL2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs1161557499, COSV61154120; called by muse, mutect2, varscan2
- ENC1 | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56628682; called by muse, mutect2, varscan2
- ENTPD1 | c.1074G>A p.G358= | Splice Region (SNP) | VAF 13/182 reads (7%) | catalogued as COSV64600195; called by muse, mutect2
- EPHA3 | c.1826T>C p.V609A | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60695381; called by muse, mutect2, varscan2
- F2 | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100319686, COSV61315500; called by muse, mutect2, varscan2
- OGDHL | c.1029G>C p.E343D | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as COSV65101125, COSV65105249; called by muse, mutect2, varscan2
- PCDHGB4 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53905215; called by muse, mutect2, varscan2
- RBFA | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV51532902; called by muse, mutect2, varscan2
- SERTAD2 | c.670T>A p.S224T | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs780025697, COSV57639685; called by muse, mutect2, varscan2
- SNAI2 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs200799419, COSV50078664; called by muse, mutect2, varscan2
- TMEM69 | c.412T>C p.S138P | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63431931; called by muse, mutect2, varscan2
- TSPAN19 | c.544A>T p.T182S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.852); catalogued as COSV70813417; called by muse, mutect2, varscan2
- WDR90 | c.1333T>G p.C445G | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV53466803; called by muse, mutect2
- ZFHX4 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); catalogued as COSV50520822; called by muse, varscan2
- ZFHX4 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs1405979515, COSV50521139; called by muse, varscan2
- ATRX | c.5037_5042del p.M1679_I1680del | In Frame Del (DEL) | VAF 206/260 reads (79%) | called by mutect2, pindel, varscan2
- GTF2H1 | c.865del p.A289Lfs*7 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- ACADSB | c.1261T>C p.L421= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as COSV62550335; called by muse, mutect2, varscan2
- ANKRD13B | c.1443G>A p.A481= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61470180; called by muse, varscan2
- CYP4F8 | c.1071G>A p.E357= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV57853240, COSV57855237; called by muse, mutect2, varscan2
- DDN | c.1374G>A p.T458= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs1324546765, COSV60291611; called by muse, mutect2, varscan2
- DKKL1 | c.27C>T p.P9= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1052296313, COSV55561578, COSV99678774; called by muse, mutect2, varscan2
- FOXN1 | c.132C>T p.A44= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs1323650301, COSV56880653; called by muse, mutect2, varscan2
- FRAS1 | c.9603C>A p.P3201= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53591148, COSV53592433; called by muse, mutect2, varscan2
- NPDC1 | c.882C>G p.A294= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV58663544; called by muse, mutect2, varscan2
- TRPC4 | c.594C>T p.N198= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1388031609, COSV58991629; called by muse, mutect2, varscan2
- ZNF710 | c.465C>T p.A155= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs552089563, COSV51561780; called by muse, mutect2, varscan2
